TCGA case TCGA-EY-A1GU — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Corpus uteri; Tissue source site: University of North Carolina. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5dd28537-d24f-4a6d-a454-6f64cf37e16a

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 66 years; Vital status: Dead; Days to death: 997 days (2.7 years).

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 66.5 years (24,304 days); Year of diagnosis: 2010; Method of diagnosis: Biopsy; FIGO stage: Stage IB; FIGO staging edition year: 2009; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 997 days (2.7 years).
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 0; Lymph nodes tested: 11.
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 94.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 0; Lymph nodes tested: 5.
   Treatment given: Treatment type: Brachytherapy, High Dose; Treatment intent type: Adjuvant; Days to treatment start: 94 days; Days to treatment end: 104 days; Treatment dose: 2,100 cGy; Course number: 1; Number of fractions: 3; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Surgery, Minimally Invasive; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.

Follow-up (4 entries)
- Days to follow up: 259 days; Disease response: Tumor Free.
- Days to follow up: 378 days (1.0 years); Disease response: Tumor Free.
- Days to follow up: 997 days (2.7 years); Disease response: Tumor Free.
- Peritoneal washing results: Negative; Timepoint: Initial Diagnosis.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 90 kg; Height: 160 cm; BMI: 35.2.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used; Hormonal replacement therapy status: No; Menopause status: Postmenopausal; Number of pregnancies: 4+; Pregnancy outcome: Full Term Birth, NOS; Risk factors: Diabetes, NOS / Hypertension.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EY-A1GU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 380 mg.
  Slide TCGA-EY-A1GU-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 15; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 40.
- Sample TCGA-EY-A1GU-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EY-A1GU-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: Tumor free; Submitted tumor site: Endometrial; Histologic diagnosis: Endometrioid endometrial adenocarcinoma; Method initial path diagnosis: Office Endometrial Biopsy; Surgical approach at diagnosis: Minimally Invasive.
- Follow-up form 1: History menopausal hormone therapy: No, I have never taken menopausal hormone therapy; Hypertension diagnosis: Yes; Diabetes diagnosis indicator: Yes; History colorectal cancer: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.
- Radiation treatment: Radiation type other: Vaginal cylinder HDR.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 997 days; disease-specific survival: no event (censored), 997 days; disease-free interval: no event (censored), 997 days; progression-free interval: no event (censored), 997 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-EY-A1GU-01): tumor purity 0.81, ploidy 2.07, whole-genome doublings 0 (call status: legacy_call).
